Somatic mutation profile of tumor specimen TCGA-86-8074-01A (aliquot TCGA-86-8074-01A-11D-2238-08) from TCGA case TCGA-86-8074, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.6 years (22,862 days).
Specimen TCGA-86-8074-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3934f06-2c19-40b7-88dc-b46d1a573bdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8074-10A (Blood Derived Normal), aliquot TCGA-86-8074-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61300c06-3272-45e4-b19f-94dfd276debd

The open-access MAF lists 76 somatic variants for this specimen: 60 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 13, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Intron 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 21/118 reads (18%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ADAMTSL3 | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54436178; called by mutect2, varscan2
- ADCY8 | c.1109A>C p.Q370P | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV53896362; called by muse, mutect2
- APOB | c.6519A>C p.Q2173H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51923181; called by muse, mutect2
- ARFGEF3 | c.2309A>G p.K770R | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52450110; called by muse, mutect2, varscan2
- ARPP21 | c.1810G>T p.G604* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV51792153, COSV51806245; called by muse, mutect2, varscan2
- BBC3 | c.647C>T p.T216I (on ENST00000449228 / NM_001127240.3; = p.P182S on NM_014417.5) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV56262526; called by muse, varscan2
- BUB1 | c.2518A>T p.R840* | Nonsense Mutation (SNP) | VAF 26/123 reads (21%) | catalogued as COSV57061199; called by muse, mutect2, varscan2
- C6orf89 | c.254T>C p.L85S (on ENST00000373685; = p.L92S on NM_152734.4) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.698); catalogued as COSV62101009; called by muse, mutect2, varscan2
- CCDC178 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV55759351; called by mutect2, varscan2
- CCDC39 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as rs1047910260, CM131301, COSV56478601; called by muse, mutect2, varscan2
- CD93 | c.1907A>G p.E636G | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); catalogued as COSV55663190; called by muse, mutect2, varscan2
- CENPH | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV51584153; called by muse, mutect2, varscan2
- CEP76 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV50865513; called by muse, mutect2, varscan2
- CLIP4 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60747506; called by muse, mutect2, varscan2
- COL4A5 | c.1450T>G p.C484G | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as COSV60356092; called by muse, mutect2, varscan2
- CSMD3 | c.9470C>T p.A3157V (on ENST00000297405 / NM_001363185.1; = p.A2988V on NM_052900.3) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.648); catalogued as rs1389987081, COSV52102748; called by muse, mutect2
- CSMD3 | c.879T>G p.D293E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52102779; called by muse, mutect2, varscan2
- DNAH2 | c.11173C>A p.P3725T | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66716322; called by muse, mutect2, varscan2
- EPHB1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 112/301 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.235); catalogued as rs183234182; called by muse, mutect2, varscan2
- EPHB1 | c.2875G>T p.A959S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV67654049, COSV67667299; called by muse, mutect2, varscan2
- FAM47A | c.1847G>C p.G616A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60493677, COSV60493979; called by muse, mutect2, varscan2
- FAM78B | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57975181; called by muse, mutect2, varscan2
- FAM91A1 | c.2338G>C p.A780P | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.134); catalogued as COSV58235667; called by muse, mutect2, varscan2
- FANCM | c.1333T>G p.Y445D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV57497213; called by muse, mutect2, varscan2
- GPS1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.309); catalogued as COSV57647660; called by muse, mutect2, varscan2
- H2AC8 | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55126172; called by muse, mutect2, varscan2
- HDAC9 | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV67766146; called by muse, mutect2, varscan2
- INSRR | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs745947130, COSV63870691, COSV63870901; called by muse, mutect2, varscan2
- KLRB1 | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57589204; called by muse, mutect2
- KTI12 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.071); catalogued as COSV65405581; called by muse, mutect2, varscan2
- MAP3K9 | c.1567+1G>T p.X523_splice | Splice Site (SNP) | VAF 27/125 reads (22%) | catalogued as COSV67119868; called by muse, mutect2, varscan2
- MBD5 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV68695754; called by muse, mutect2, varscan2
- MYO7A | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68683420; called by muse, mutect2, varscan2
- MYOM2 | c.2665G>T p.A889S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV50702170; called by muse, mutect2, varscan2
- NDOR1 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61286333; called by muse, mutect2, varscan2
- NHS | c.1835A>C p.N612T | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV66271279; called by muse, mutect2
- NPFFR2 | c.1411A>G p.S471G | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV58146286, COSV58146643; called by muse, mutect2
- OR1D5 | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.999); catalogued as COSV73859477; called by muse, mutect2, varscan2
- OR5B2 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV56907415, COSV56907531; called by muse, mutect2, varscan2
- PPP1R16B | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs751756577, COSV55374174; called by mutect2, varscan2
- PRAMEF15 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs1164716403; called by muse, mutect2
- RGS13 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67345607; called by muse, mutect2, varscan2
- RP1 | c.2204A>T p.D735V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV55110035; called by muse, mutect2, varscan2
- RUNDC1 | c.617A>G p.Y206C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.594); catalogued as COSV64511455; called by muse, mutect2, varscan2
- SCN10A | c.113G>T p.R38I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV71860242; called by muse, mutect2, varscan2
- SEC23IP | c.2603C>G p.S868C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV64830723; called by muse, mutect2, varscan2
- SELE | c.627C>A p.S209R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV60973905; called by muse, mutect2, varscan2
- SLC10A3 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54835549; called by muse, mutect2, varscan2
- ST6GAL1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | PolyPhen possibly damaging (0.874); catalogued as COSV51466123, COSV51475694; called by muse, mutect2, varscan2
- TP53I11 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57532593; called by muse, mutect2, varscan2
- TSC1 | c.3322G>C p.G1108R | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV53763446, COSV53763674; called by muse, mutect2, varscan2
- USF2 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1306446947, COSV55886427; called by muse, mutect2, varscan2
- VANGL2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs771137916, COSV100925534, COSV63603989; called by muse, mutect2, varscan2
- ZNF334 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV61617958; called by muse, mutect2, varscan2
- CR1 | c.2602+3_2602+6del p.X868_splice | Splice Site (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- RB1 | c.393_396del p.F131Lfs*4 | Frame Shift Del (DEL) | VAF 16/24 reads (67%) | called by mutect2, pindel, varscan2
- RBKS | c.112del p.T38Lfs*31 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by pindel, varscan2
- ZSCAN30 | c.552_553del p.D185Wfs*17 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by pindel, varscan2
- COL4A5 | c.1656T>G p.T552= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV60356102; called by muse, mutect2, varscan2
- CSMD3 | c.1248T>C p.S416= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV52102764, COSV52330539; called by muse, mutect2, varscan2
- DAB2 | c.2124G>A p.L708= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs760915155, COSV57913384; called by muse, mutect2
- DBH | c.228C>A p.L76= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55039698, COSV55040601, COSV99708149; called by muse, mutect2, varscan2
- DNAH2 | c.6957C>T p.F2319= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV66716318; called by muse, mutect2, varscan2
- FLG | c.3948A>G p.R1316= | Silent (SNP) | VAF 129/382 reads (34%) | catalogued as COSV64236433; called by muse, mutect2, varscan2
- ISG20L2 | c.24G>C p.L8= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV57459364; called by muse, mutect2, varscan2
- LRRC27 | c.627G>A p.A209= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs758352841, COSV59806984; called by muse, mutect2, varscan2
- NOS1 | c.289C>T p.L97= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1479219448, COSV57606647; called by muse, mutect2, varscan2
- RYR2 | c.13050G>A p.E4350= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV63661860; called by muse, mutect2, varscan2
- SEMA3E | c.2217G>A p.R739= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV57079671; called by muse, mutect2, varscan2
- UTP4 | c.897G>A p.A299= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs554532839, COSV58732062; called by muse, mutect2, varscan2
- ZGPAT | c.144G>A p.E48= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1262726710, COSV60831048; called by muse, varscan2
- GLOD4 | chr17:783137 C>T | 5'Flank (SNP) | VAF 5/44 reads (11%) | catalogued as COSV56752435; called by muse, mutect2, varscan2
- MIR450A2 | n.100G>T | RNA (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- TBX5 | c.982+62G>C | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as rs987987717, COSV100090928, COSV100091160; called by muse, mutect2, varscan2
